Gene-level copy-number profile of tumor specimen HCM-STAN-0841-C18-01A from HCMI case HCM-STAN-0841-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 62.2 years (22,736 days).
Specimen HCM-STAN-0841-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 57ad8947-f673-4c24-8377-785b880cdc97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0841-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/ba5aa869-8c0f-42a9-a62c-60d88fd6fd2d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 23; copy number 2: 6,871; copy number 3: 16,046; copy number 4: 26,944; copy number 5: 738; copy number 6: 5,493; copy number 7: 768; copy number 8: 923; copy number 9: 549; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr15:21,307,749–21,307,855, 1 gene: RNU6-1235P.
- chr15:30,098,826–30,131,757, 3 genes: DNM1P28, ULK4P3, U8.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–3): MIR1233-2.
- chr15:67,142,734–67,146,939, 1 gene (within-gene range 0–3): AC012568.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 551 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:63,183,096–74,830,080, 93 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr13:75,237,944–87,380,258, 102 genes, copy number 9 (broad region; genes not listed).
- chr13:87,427,200–87,447,235, 1 gene, copy number 9 (within-gene range 8–9): AL360267.1.
- chr13:88,494,789–114,337,626, 353 genes, copy number 9 (broad region; genes not listed).
- chr20:19,756,390–19,823,943, 2 genes, copy number 13: AL121761.1, RPL12P12.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
